Gene-level copy-number profile of tumor specimen 1105242 from CPTAC case C229764, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105242: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 64d08121-e9be-463e-a3cc-944df6d75de6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105275 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/22adc267-f683-48d4-9748-6ccfdd2216b2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 531; copy number 1: 5,386; copy number 2: 44,362; copy number 3: 8,437; copy number 4: 17; copy number 5: 8; copy number 6: 168; copy number 7: 4.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:48,009,873–48,119,455, 4 genes: AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.
- chr21:9,068,361–9,129,752, 3 genes: TEKT4P2, SOWAHCP2, CR392039.2.
- chr22:23,949,918–23,991,421, 10 genes: AP000350.3, GSTT2B, AC253536.2, DDTL, AC253536.6, DDT, AC253536.7, AC253536.1, AC253536.5, GSTT2.
- chr22:42,500,568–42,519,796, 2 genes: SERHL, RRP7A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 180 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:173,396,284–174,286,644, 3 genes, copy number 6 (within-gene range 3–6): NLGN1, AC092967.1, NLGN1-AS1.
- chr3:174,302,944–175,810,548, 7 genes, copy number 5 (within-gene range 4–7): ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2.
- chr3:175,473,919–175,477,602, 1 gene, copy number 5: AC008180.3.
- chr3:176,113,702–184,556,918, 169 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,386. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
